Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AC-01A (Primary Tumor).

[page 1 of 5]
1cd-0-3

Carcinoma, Urothelial, NOS 8120/3
Site Code bladder, NOS C67.912/30/10
hr**SURGICAL PATHOLOGY REPORT**
Reformatted Report**Patient Name:****Med. Rec. #:**

DOB: (Age: 72)

Gender:

M

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Other Related Data:

Billing Type:

INPATIENT

Financial Number:

Clinical Diagnosis & History:

72 y/o male with h/o T2 TCC bladder.

Specimens Submitted:

- 1: SP: Right distal ureter (
- 2: SP: Left distal ureter
- 3: SP: Bladder and prostate (
- 4: SP: Right vas deferens
- 5: SP: Left vas deferens
- 6: SP: Left pelvic lymph nodes (
- 7: SP: Right pelvic lymph nodes (
- 8: SP: Right distal ureter (

DIAGNOSIS:

- 1) URETER, RIGHT DISTAL; BIOPSY:
- SEGMENT OF BENIGN URETER.
- 2) URETER, LEFT DISTAL; BIOPSY:
- SEGMENT OF BENIGN URETER.
- 3) BLADDER AND PROSTATE; CYSTOPROSTATECTOMY:
- HIGH GRADE INVASIVE UROTHELIAL CARCINOMA. NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED. NO IN SITU CARCINOMA IS IDENTIFIED. THE TUMOR INVADES INTO THE PERIVESICAL SOFT TISSUES (pt3b). LYMPHOVASCULAR INVASION IS PRESENT IN THE PROSTATE. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- ADENOCARCINOMA OF PROSTATE. THE GLEASON'S GRADE IS 3+3=6/10. THE TUMOR INVOLVES THE FOLLOWING QUADRANT(S): RIGHT POSTERIOR, RIGHT ANTERIOR AND LEFT ANTERIOR. NO PERINEURAL INVASION IS IDENTIFIED. MULTICENTRIC FOCI OF INVASIVE CARCINOMA ARE PRESENT. THE TUMOR IS CONFINED TO THE PROSTATE. THE SEMINAL VESICLES ARE FREE OF TUMOR. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE REMAINING PROSTATE SHOWS THE FOLLOWING ABNORMALITY(IES): PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN). THE PATHOLOGIC STAGE (AJCC 1997) IS: pt2b.
- 4) VAS DEFERENS, RIGHT; RESECTION:
- SEGMENT OF BENIGN VAS DEFERENS.

Case is (click):		

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

- 5) VAS DEFERENS, LEFT; RESECTION:
- SEGMENT OF BENIGN VAS DEFERENS.
- 6) LYMPH NODES, LEFT PELVIC; DISSECTION:
- ELEVEN LYMPH NODES, NEGATIVE FOR TUMOR (0/11).
- 7) LYMPH NODES, RIGHT PELVIC; DISSECTION:
- ELEVEN LYMPH NODES, NEGATIVE FOR TUMOR (0/11).
- 8) URETER, RIGHT DISTAL; EXCISION:
- SEGMENT OF BENIGN URETER.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Right Distal Ureter". It consists of a 0.3 x 0.2 cm tubular piece of tan-pink soft tissue. The specimen is entirely frozen and subsequently submitted for permanent sections.

Summary of Sections:
FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled "Left Distal Ureter". It consists of a 0.3 x 0.2 cm tubular piece of tan-pink soft tissue. The specimen is entirely frozen and subsequently submitted for permanent sections.

Summary of Sections:
FSC - frozen section control

3) The specimen is received fresh, labeled "Bladder and Prostate". It consists of a 24 x 14 x 5.8 cm cystoprostatectomy specimen with attached overlying adipose tissue. The left half of the prostate is inked blue and the right half is inked green. In the left half of the bladder there is a palpable tumor mass which appears to occupy the left lateral and anterior wall. The overlying adipose in this area is inked black. There is approximately 3 cm in length of ureter on the left and 4.5 cm of ureter on the right. Both ureters are probe patent. The specimen is opened along the anterior wall to reveal a 7.5 X 6.8 X 3.3 cm, fungating, ulcerated tumor mass occupying the central and lateral left posterior bladder wall as well as the anterior bladder wall. The tumor is left lateral and anterior and is adjacent to, but not occluding, the left ureteral orifice within the bladder. The uninvolved bladder mucosa is hemorrhagic and rugose. The trigone is not grossly involved by tumor. Serial sectioning of the tumor reveals the cut surfaces are yellow-white and necrotic. The tumor invades the muscularis mucosa, however,

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

it does not appear to extend through it into the overlying soft tissue. Representative sections of tumor and bladder mucosa are submitted. The entire prostate is submitted from anterior to posterior and designated A through H respectively. The specimen is photographed and portions of tumor are submitted to TPS.

Summary of Sections:

PU - prostatic urethra
LUO - left ureteral orifice
LUM - left ureteral margin
RUM - right ureteral margin
RUO - right ureteral orifice
LLAT - left lateral bladder
POST - posterior bladder mucosa
TRIG - trigone
DOME - dome
TLL - tumor left lateral
T - tumor
ST - soft tissue overlying tumor
RSVD - right seminal vesicle and vas deferens
LSV - left seminal vesicle
RVD - right vas deferens
RA - right segment A
LA - left segment B
RB - right segment B
LB - left segment B
RC - right segment C
LC - left segment C
RAD - right anterior segment D
RPD - right posterior segment D
LAD - left anterior segment D
LPD - left posterior segment D
RAE - right anterior segment E
RPE - right posterior segment E
LAE - left anterior segment E
LPE - left posterior segment E
F,G,H - serially sectioned prostate

4) The specimen is received in formalin, labeled "Right vas deferens". It consists of a right vas deferens measuring 9.5 cm in length and 0.4 cm partially surrounded by fibroadipose tissue. The specimen is submitted representatively.

Summary of Sections:

SM - surgical margin
RS - representative sections

5) The specimen is received in formalin, labeled "Left vas deferens". It consists of a left vas deferens measuring 9.5 cm in length and 0.4 cm partially surrounded by fibroadipose tissue. The specimen is submitted representatively.

Summary of Sections:

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

SM - surgical margin
RS - representative sections

6) The specimen is received in formalin, labeled "Left pelvic lymph nodes". It consists of multiple irregular pieces of yellowish tan fibroadipose tissue measuring 5.5 x 3.0 x 2.0 cm in aggregate which contains several lymph nodes. The specimen is submitted entirely.

Summary of Sections:
U - undesignated

7) The specimen is received in formalin, labeled "Right pelvic lymph nodes". It consists of multiple irregular pieces of yellowish tan fibroadipose tissue measuring 5.0 x 5.0 x 1.0 cm in aggregate which contains several lymph nodes. The specimen is submitted entirely.

Summary of Sections:
U - undesignated

8) The specimen is received in formalin, labeled "Right distal ureter". It consists of a portion of ureter which is surrounded by reddish tan fibroadipose tissue measuring 1.0 cm in length and up to 0.4 cm in diameter. At one end of the specimen is oriented by a suture. The specimen is submitted entirely.

Summary of Sections:
ST - tip with suture
T - other tip
RS - middle portion

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	FSC		1	1	Y
3	DOME		1	1	N
	F		1	1	
	G		1	1	
	H		1	1	
	LA		1	1	
	LAD		1	1	
	LAE		1	1	
	LB		1	1	
	LC		1	1	
	LLAT		1	1	
	LPD		1	1	
	LPE		1	1	
	LSV		1	1	
	LUM		1	1	
	LUO		2	2	

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

	LVD	1	1	
	POST	1	1	
	PU	1	1	
	RA	1	1	
	RAD	1	1	
	RAE	1	1	
	RB	1	1	
	RC	1	1	
	RPD	1	1	
	RPE	1	1	
	RSVD	1	2	
	RUM	1	1	
	RUO	2	2	
	ST	1	1	
	T	5	5	
	TLL	1	-	
	TRIG	1	1	
4	RS	1	2	N
	SM	1	2	
5	RS	1	2	N
	SM	1	2	
6	U	6	M	Y
7	U	6	M	Y
8	RS	1	2	Y
	ST	1	1	
	T	1	1	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 9e2e9421-b84f-4abc-8841-22b5673372ad (TCGA-DK-A1AC.6A32EB34-E83A-4665-8DEA-F4CEB7CBF52D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).